HCMI case HCM-BROD-0103-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1aad065b-567d-4f08-9cf0-bcc57e8ef496

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2005; Vital status: Dead; Days to death: 302 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 11.8 years (4,295 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation, Proton Beam; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 50 days; Days to treatment end: 92 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 134 days; Days to treatment end: 226 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 134 days; Days to treatment end: 226 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 302 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 0, day 37.

Molecular and laboratory tests
- IDH1 (IHC): Positive; Amino-acid change: R132H.
- IDH1 substitution (IHC): Positive; Amino-acid change: R132H.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51.2 kg; Height: 152.3 cm; BMI: 22.1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0103-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0103-C71-01A-01-S1-HE: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 86; Percent normal cells: 11; Percent necrosis: 20; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0103-C71-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 88; Percent normal cells: 11; Percent necrosis: 10; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0103-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0103-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
